Surgical pathology report (de-identified scan), TCGA case TCGA-33-4533, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-4533-01A (Primary Tumor).

FINAL DIAGNOSIS ----- Pathologist: [REDACTED]

1. LEFT LUNG (RESECTION): POORLY DIFFERENTIATED PLEOMORPHIC NON-SMALL CELL CARCINOMA OF THE LUNG. THE CARCINOMA SHOWS BOTH DISTINCTIVE SQUAMOUS AND HIGH-GRADE SPINDLE CELL FEATURES. THE CARCINOMA INVOLVES THE PLEURAL SURFACE. ALL OTHER SURGICAL MARGINS OF RESECTION ARE NEGATIVE FOR TUMOR. ONE (1) HILAR LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR. THE UNINVOLVED LUNG PARENCHYMA DEMONSTRATES EMPHYSEMATOUS CHANGE. SEE NOTE.

2. LYMPH NODE, STATION 5 (BX): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

3. LYMPH NODE, L11 (BX.): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 9ec018f9-0fa1-49cd-a696-22e67fb91f8c (TCGA-33-4533.1791E931-CCED-44E6-B530-21BBA650CC8C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).